Somatic mutation profile of tumor specimen TCGA-AX-A063-01A (aliquot TCGA-AX-A063-01A-11W-A027-09) from TCGA case TCGA-AX-A063, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 63.1 years (23,045 days).
Specimen TCGA-AX-A063-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fca6d9d1-6ade-41b7-b167-8bd9085301af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A063-10A (Blood Derived Normal), aliquot TCGA-AX-A063-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92849deb-feba-45f9-8473-86e23d0957a5

The open-access MAF lists 1,276 somatic variants for this specimen: 974 protein-altering or splice-affecting, 270 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 739, Silent 270, Frame Shift Del 144, Nonsense Mutation 27, Frame Shift Ins 27, Splice Site 18, Intron 14, In Frame Del 8, RNA 8, Splice Region 8, 3'Flank 4, 3'UTR 4.

Variants (750 of 1,276; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 83/208 reads (40%) | hotspot (GDC flag); catalogued as rs387906846, CM122485, COSV61371872; ClinVar: pathogenic; called by muse, varscan2
- CWC27 | c.1002del p.V335* | Frame Shift Del (DEL) | VAF 58/175 reads (33%) | catalogued as rs752159903; ClinVar: pathogenic; called by mutect2, varscan2
- EIF2B2 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs372548739, CM152520, COSV56720257; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.1145G>A p.C382Y | Missense Mutation (SNP) | VAF 30/122 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1057519900, COSV60662008; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.600dup p.F201Lfs*15 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs752657203; ClinVar: pathogenic; called by mutect2, varscan2
- MAX | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52415800; called by muse, mutect2, varscan2
- METTL14 | c.893G>C p.R298P | Missense Mutation (SNP) | VAF 145/396 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310162, COSV66310354; called by muse, mutect2, varscan2
- PEX16 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064794320, CM1311264, COSV53804762; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1699A>G p.K567E (on ENST00000521381 / NM_181523.3; = p.K297E on NM_181504.4) | Missense Mutation (SNP) | VAF 84/211 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57123609; called by muse, mutect2, varscan2
- PPM1D | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 51/150 reads (34%) | catalogued as rs779070661, CM1414538, COSV59954404; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.48_49del p.Y16* | Nonsense Mutation (DEL) | VAF 28/95 reads (29%) | hotspot (GDC flag); catalogued as COSV64308875; called by mutect2, pindel, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- AAAS | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs768786904, COSV52934678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABAT | c.1429A>G p.T477A | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1292109941, COSV51629325; called by muse, mutect2, varscan2
- ABCA12 | c.5506A>G p.T1836A (on ENST00000272895 / NM_173076.3; = p.T1518A on NM_015657.3) | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as rs778106152, COSV55978672; called by muse, mutect2, varscan2
- ABCA6 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs775048252, COSV99447941; called by muse, mutect2
- ABCB6 | c.2008C>T p.P670S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54701559; called by mutect2, varscan2
- ABCC8 | c.3158G>T p.S1053I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV56858854; called by muse, mutect2, varscan2
- ABHD2 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100756502; called by muse, mutect2
- ABL1 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs765425928, COSV59337046; called by muse, mutect2, varscan2
- AC131160.1 | c.357G>A p.W119* | Nonsense Mutation (SNP) | VAF 32/245 reads (13%) | catalogued as COSV57702704; called by muse, mutect2, varscan2
- ACACB | c.4192del p.L1398Sfs*26 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs1565953344, COSV58128358; called by mutect2, pindel, varscan2
- ACKR1 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63674142, COSV63674912; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 262/456 reads (57%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM12 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760438496, COSV100901660, COSV100901733; called by muse, mutect2, varscan2
- ADAM15 | c.626T>C p.V209A | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV55064113; called by muse, mutect2, varscan2
- ADAM18 | c.1004G>A p.C335Y | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55856564; called by muse, mutect2, varscan2
- ADAMTS10 | c.2293del p.Q765Sfs*7 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | catalogued as rs782743337; called by mutect2, pindel, varscan2
- ADAMTS12 | c.2524A>G p.T842A | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV61282955; called by muse, mutect2, varscan2
- ADAMTS3 | c.1988T>G p.L663R | Missense Mutation (SNP) | VAF 126/295 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV54404732; called by muse, mutect2, varscan2
- ADCY6 | c.1086del p.E363Kfs*3 | Frame Shift Del (DEL) | VAF 41/184 reads (22%) | catalogued as rs1565648463; called by mutect2, pindel, varscan2
- ADGRE1 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 102/284 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs188529490; called by muse, mutect2, varscan2
- ADGRG4 | c.7059A>G p.I2353M | Missense Mutation (SNP) | VAF 101/760 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54969027; called by muse, mutect2, varscan2
- ADGRG4 | c.8915C>T p.A2972V | Missense Mutation (SNP) | VAF 33/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54969041; called by muse, mutect2, varscan2
- AEBP1 | c.3407A>G p.E1136G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV56261789; called by muse, mutect2, varscan2
- AFDN | c.4336A>G p.T1446A | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60059068; called by muse, mutect2, varscan2
- AGAP1 | c.2240C>T p.T747M (on ENST00000304032 / NM_001037131.3; = p.T694M on NM_014914.5) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.843); catalogued as COSV58332456; called by muse, mutect2, varscan2
- AGO2 | c.2469C>T p.D823= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as rs777138988, COSV55050363; called by muse, mutect2, varscan2
- AGPAT3 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs962293850, COSV52374557; called by muse, mutect2, varscan2
- AGTR2 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 217/662 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.976); catalogued as COSV64157181; called by muse, mutect2, varscan2
- AIMP2 | c.185T>G p.I62S | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56152251; called by muse, mutect2, varscan2
- AKAP1 | c.1559G>A p.C520Y | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV58473496; called by muse, mutect2, varscan2
- AKAP13 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV63471600; called by muse, mutect2, varscan2
- AKAP3 | c.2047A>C p.I683L | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV57421531; called by muse, mutect2, varscan2
- AKNAD1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs202065262, COSV62201555; called by muse, mutect2, varscan2
- AL121899.2 | c.1327A>G p.S443G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67352576; called by muse, mutect2, varscan2
- ALAS2 | c.1567del p.H523Tfs*6 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as COSV58188902; called by mutect2, pindel, varscan2
- ALB | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1356964167, COSV55743353; called by muse, mutect2, varscan2
- ALCAM | c.1661C>T p.S554L | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60255995; called by muse, mutect2, varscan2
- ALDH18A1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 19/248 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV100973317; called by muse, mutect2
- ALDH5A1 | c.1187T>G p.V396G | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100708942; called by muse, mutect2
- ALOX15 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs1417579437, COSV53401285; called by muse, mutect2, varscan2
- ALPK1 | c.3587A>T p.Q1196L | Missense Mutation (SNP) | VAF 84/346 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as COSV51592959; called by muse, mutect2, varscan2
- ALYREF | c.472G>A p.V158M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV58669325; called by muse, mutect2, varscan2
- ANK3 | c.2813A>G p.E938G (on ENST00000280772 / NM_001320874.2; = p.E72G on NM_001149.3) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99782843; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.7157C>T p.P2386L | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs142203317; called by muse, mutect2, varscan2
- ANKRD17 | c.1400T>C p.F467S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58228952; called by muse, mutect2, varscan2
- ANKRD20A1 | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 12/16 reads (75%) | catalogued as rs1296524808; called by mutect2, varscan2
- ANKRD55 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs752328910, COSV61951384; called by muse, mutect2, varscan2
- AP3M1 | c.576T>A p.D192E | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV62332583; called by muse, mutect2, varscan2
- AP4B1 | c.1720A>G p.T574A | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs911365743, COSV56727299; called by muse, mutect2, varscan2
- AP4S1 | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53558020; called by muse, mutect2, varscan2
- APCDD1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758870123, COSV62373522; called by muse, mutect2, varscan2
- AQP1 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.823); catalogued as COSV61268422; called by muse, mutect2, varscan2
- ARAF | c.1294T>C p.S432P | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51695588; called by muse, mutect2, varscan2
- ARAP3 | c.1121T>C p.L374P | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53355527; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | catalogued as rs773922861; called by mutect2, varscan2
- ARHGAP31 | c.4289G>A p.R1430Q | Missense Mutation (SNP) | VAF 125/322 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761090674, COSV51800267; called by muse, mutect2, varscan2
- ARHGEF11 | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63816023; called by muse, mutect2, varscan2
- ARHGEF9 | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 272/722 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs782786513, COSV53645394; called by muse, mutect2, varscan2
- ARID1A | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV61383449; called by muse, mutect2, varscan2
- ARID2 | c.4582G>A p.A1528T | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs761166036, COSV57616394; called by muse, mutect2, varscan2
- ARL14EP | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99956113; called by muse, mutect2
- ARMC2 | c.2036A>G p.E679G | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV64553682; called by muse, mutect2, varscan2
- ARSB | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as COSV53728606, COSV53730062; called by muse, mutect2, varscan2
- ASCC3 | c.6510C>A p.D2170E | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); catalogued as COSV100977032; called by muse, mutect2
- ASH1L | c.6958C>T p.H2320Y (on ENST00000368346 / NM_001366177.2; = p.H2315Y on NM_018489.3) | Missense Mutation (SNP) | VAF 89/309 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV64214764; called by muse, mutect2, varscan2
- ASPN | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs966554052, COSV100978698; called by muse, mutect2
- ASXL3 | c.6116C>A p.P2039H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV52482098; called by muse, varscan2
- ATF2 | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV51376528; called by muse, mutect2, varscan2
- ATG2B | c.4210G>A p.A1404T | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV55892353; called by muse, mutect2, varscan2
- ATM | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV53779982; called by muse, mutect2, varscan2
- ATP10A | c.4276del p.L1426Cfs*66 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as rs768534594; called by mutect2, pindel
- ATP1A1 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55194740; called by muse, mutect2, varscan2
- ATP1A4 | c.69del p.I26Sfs*6 | Frame Shift Del (DEL) | VAF 36/148 reads (24%) | catalogued as rs1467294583; called by mutect2, pindel, varscan2
- ATP2A1 | c.1766C>T p.T589M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs200285714; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATRNL1 | c.3386C>T p.T1129I | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58118892; called by muse, mutect2, varscan2
- AXDND1 | c.482T>C p.I161T | Missense Mutation (SNP) | VAF 88/351 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.156); catalogued as COSV62650091; called by muse, mutect2, varscan2
- B3GALNT1 | c.314del p.K105Sfs*14 | Frame Shift Del (DEL) | VAF 87/284 reads (31%) | catalogued as rs759975633; called by mutect2, pindel, varscan2
- B3GALT2 | c.1120T>A p.C374S | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66464614; called by muse, mutect2, varscan2
- B3GALT2 | c.1006C>G p.R336G | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.917); catalogued as COSV66464622; called by muse, mutect2, varscan2
- B3GALT2 | c.342T>A p.N114K | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as rs777270072, COSV100813643; called by muse, mutect2, varscan2
- B3GALT4 | c.925_926del p.V309Qfs*41 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs910030558; called by pindel, varscan2
- B4GAT1 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV60820906; called by muse, mutect2, varscan2
- BAZ1B | c.482G>A p.S161N | Missense Mutation (SNP) | VAF 61/525 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV59995168; called by muse, mutect2, varscan2
- BAZ2B | c.5018T>C p.V1673A | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1328542156, COSV58611421; called by muse, mutect2, varscan2
- BBS7 | c.1466A>G p.K489R | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as rs575924592, COSV52660096; called by muse, mutect2, varscan2
- BCLAF1 | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 175/459 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs34541670; called by muse, mutect2, varscan2
- BEST3 | c.1682G>T p.G561V | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.034); catalogued as COSV58306681; called by muse, mutect2, varscan2
- BHLHE41 | c.260T>C p.V87A | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54379857; called by muse, mutect2, varscan2
- BOC | c.1487G>A p.R496Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as rs770042178, COSV56352788; called by muse, mutect2, varscan2
- BORA | c.386G>A p.G129E (on ENST00000613797; = p.G54E on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.149); catalogued as COSV100909788; called by muse, mutect2
- BPIFB1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs149436006, COSV53605013; called by muse, mutect2, varscan2
- BTK | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100438005; called by muse, mutect2
- BTRC | c.1313A>G p.Y438C (on ENST00000370187 / NM_033637.4; = p.Y402C on NM_003939.5) | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64581349; called by muse, mutect2, varscan2
- C14orf93 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1389323910, COSV54440549; called by muse, mutect2, varscan2
- C1R | c.2123T>G p.V708G (on ENST00000536053 / NM_001354346.2; = p.V694G on NM_001733.7) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV73383066; called by muse, mutect2, varscan2
- C2orf16 | c.4652G>A p.R1551H | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs771049006, COSV62678717; called by muse, mutect2, varscan2
- C4BPA | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV100891291; called by muse, mutect2
- C4BPB | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 15/192 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as rs769703116, COSV54691930; called by muse, mutect2
- C7orf61 | c.571del p.R191Dfs*8 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs767078637; called by mutect2, varscan2
- C8orf34 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 119/313 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61372387; called by muse, mutect2, varscan2
- CA14 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 91/304 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs782127819, COSV52528330; called by muse, mutect2, varscan2
- CA8 | c.494T>G p.I165S | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV58775120; called by muse, mutect2, varscan2
- CACNA1C | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59753193; called by muse, mutect2, varscan2
- CACNA1D | c.5032G>A p.V1678M (on ENST00000350061 / NM_001128840.3; = p.V1698M on NM_000720.4) | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs773810643, COSV55467452; called by muse, mutect2, varscan2
- CACNA1S | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs771706267, COSV62944632; called by muse, mutect2, varscan2
- CACNA2D4 | c.896G>T p.S299I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54963112; called by muse, mutect2, varscan2
- CACNB1 | c.1432C>A p.L478I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV60000611; called by muse, mutect2, varscan2
- CAD | c.1379T>C p.V460A | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53032747; called by muse, mutect2, varscan2
- CALD1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100724139, COSV100724648; called by muse, mutect2
- CAMTA1 | c.4787C>T p.A1596V | Missense Mutation (SNP) | VAF 37/329 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57931480; called by muse, mutect2, varscan2
- CAND1 | c.2045G>A p.S682N | Missense Mutation (SNP) | VAF 22/297 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs1374053592, COSV101607362; called by muse, mutect2
- CARD8 | c.929G>A p.R310H (on ENST00000651546 / NM_001184900.3; = p.R260H on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.392); catalogued as rs1375869627, COSV62875419; called by muse, mutect2, varscan2
- CATSPER1 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | catalogued as COSV56414039; called by muse, mutect2, varscan2
- CATSPERG | c.3188C>A p.P1063H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.443); catalogued as COSV53047193, COSV53054683; called by muse, mutect2, varscan2
- CBLL1 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 199/567 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV56031047; called by muse, mutect2, varscan2
- CBLN4 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV99290466, COSV99290798; called by muse, mutect2
- CC2D2B | c.904C>T p.H302Y | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1421009682, COSV100729595, COSV60357567; called by muse, mutect2, varscan2
- CCDC38 | c.1686del p.F562Lfs*4 | Frame Shift Del (DEL) | VAF 25/114 reads (22%) | catalogued as rs769501825; called by mutect2, pindel, varscan2
- CCDC65 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1223874594, COSV56740499; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC70 | c.19A>G p.S7G | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as COSV54431182; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 34/99 reads (34%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC77 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs374200726; called by muse, varscan2
- CCKAR | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV55164454; called by muse, mutect2, varscan2
- CCND1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57121200, COSV57123646; called by muse, mutect2, varscan2
- CD27 | c.394T>C p.S132P | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1316596380, COSV56948939; called by muse, mutect2, varscan2
- CD47 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 153/465 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs867685532, COSV62528783; called by muse, mutect2, varscan2
- CD5L | c.850C>T p.Q284* | Nonsense Mutation (SNP) | VAF 23/257 reads (9%) | catalogued as rs1439521988, COSV100941224; called by muse, mutect2
- CDH23 | c.5394G>T p.E1798D | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as COSV56494190; called by muse, mutect2, varscan2
- CDH4 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV64677889; called by muse, mutect2, varscan2
- CDK14 | c.907C>A p.L303I (on ENST00000380050 / NM_001287135.2; = p.L285I on NM_012395.3) | Missense Mutation (SNP) | VAF 162/477 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56054992; called by muse, mutect2, varscan2
- CDK17 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 70/195 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.164); catalogued as COSV54134352; called by muse, mutect2, varscan2
- CEACAM21 | c.613A>G p.R205G | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV51817033; called by muse, mutect2, varscan2
- CELSR1 | c.3199C>T p.R1067W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760767669, COSV53101500; called by muse, mutect2, varscan2
- CEMIP | c.2881G>A p.V961I | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs748502287, COSV55001377; called by muse, mutect2, varscan2
- CENPE | c.5180A>G p.H1727R | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54392244; called by muse, mutect2, varscan2
- CENPL | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV61893141; called by muse, mutect2, varscan2
- CEP152 | c.568T>C p.Y190H | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV57865834; called by muse, mutect2, varscan2
- CEP290 | c.3090G>T p.Q1030H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV58357220; called by muse, mutect2, varscan2
- CEP89 | c.644G>A p.C215Y | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs1464924436, COSV59868361; called by muse, mutect2, varscan2
- CFAP251 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 75/341 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV55840922; called by muse, mutect2, varscan2
- CFAP251 | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV56611559, COSV56616682; called by muse, mutect2, varscan2
- CHI3L2 | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 162/424 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63875033; called by muse, mutect2, varscan2
- CHIT1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.04); catalogued as COSV55150257; called by muse, mutect2, varscan2
- CHL1 | c.2015T>C p.V672A (on ENST00000397491 / NM_001253387.1; = p.V688A on NM_006614.4) | Missense Mutation (SNP) | VAF 60/323 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV56608868; called by muse, mutect2, varscan2
- CHRM5 | c.259T>C p.Y87H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101272073; called by muse, mutect2
- CLASP1 | c.2442_2444del p.R815del | In Frame Del (DEL) | VAF 96/278 reads (35%) | catalogued as rs749729483; called by pindel, varscan2
- CLCA1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 196/541 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.696); catalogued as rs780698919, COSV52332156; called by muse, mutect2, varscan2
- CLCN3 | c.2447T>C p.M816T | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV61628858; called by muse, mutect2, varscan2
- CLEC9A | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV63351845; called by muse, mutect2, varscan2
- CLHC1 | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs375111291, COSV63427352; called by muse, mutect2, varscan2
- CLIC6 | c.2089T>A p.S697T (on ENST00000360731 / NM_001317009.2; = p.S679T on NM_053277.3) | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV100659350; called by muse, mutect2
- CLK2 | c.1259A>G p.D420G (on ENST00000368361 / NM_001294339.2; = p.D419G on NM_003993.4) | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV56947807; called by muse, mutect2, varscan2
- CLK4 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0.076); catalogued as rs950669987, COSV100308758, COSV60321538; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSPN | c.1737del p.K580Rfs*18 | Frame Shift Del (DEL) | VAF 89/253 reads (35%) | catalogued as COSV52057932; called by mutect2, pindel, varscan2
- CNGA1 | c.1079G>A p.G360D | Missense Mutation (SNP) | VAF 137/503 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs965734036, CM152468, COSV62057353; called by muse, mutect2, varscan2
- CNOT1 | c.3772T>C p.W1258R | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99801518; called by muse, mutect2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 149/427 reads (35%) | catalogued as rs1397135931, COSV55313852; called by mutect2, pindel, varscan2
- CNR1 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62992462; called by muse, mutect2, varscan2
- CNTN1 | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 89/259 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61646508; called by muse, mutect2, varscan2
- CNTRL | c.715T>C p.F239L | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV53054503; called by muse, mutect2, varscan2
- CNTROB | c.2699del p.G900Efs*34 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as rs35508310, COSV66608279; called by mutect2, varscan2
- COG7 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.237); catalogued as COSV56153731; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 42/126 reads (33%) | catalogued as rs760493024; called by mutect2, varscan2
- COL4A2 | c.3692C>A p.P1231Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV64635441; called by muse, mutect2, varscan2
- COL7A1 | c.8137G>T p.G2713C | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM990423, COSV56477415; called by muse, mutect2, varscan2
- COPG2 | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs782811687, COSV56230121; called by muse, mutect2, varscan2
- CPSF6 | c.842G>A p.G281E | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57018839; called by muse, mutect2, varscan2
- CPT2 | c.1534T>A p.C512S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99598394; called by muse, mutect2
- CR1L | c.1327G>T p.G443W | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1354108565, COSV54332205; called by muse, mutect2, varscan2
- CRB1 | c.4091T>C p.V1364A | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV66349858; called by muse, mutect2, varscan2
- CTAGE1 | c.1462T>C p.Y488H | Missense Mutation (SNP) | VAF 225/563 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as rs765279218, COSV66945294; called by muse, mutect2, varscan2
- CTNND1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.703); catalogued as COSV62383707; called by muse, mutect2
- CTNND2 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs905659484, COSV58934168; called by muse, mutect2, varscan2
- CWF19L1 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 82/220 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV62499891; called by muse, mutect2, varscan2
- CYB5D2 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV56801306; called by muse, mutect2, varscan2
- CYP19A1 | c.1511A>G p.*504Wext*31 | Nonstop Mutation (SNP) | VAF 150/606 reads (25%) | catalogued as COSV53062946; called by muse, mutect2, varscan2
- CYP26A1 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV56420219; called by muse, mutect2, varscan2
- CYP4X1 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.611); catalogued as COSV64152060; called by muse, mutect2, varscan2
- DAGLB | c.571A>T p.S191C | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV51707301; called by muse, mutect2, varscan2
- DARS2 | c.1282A>G p.R428G | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV53409632; called by muse, mutect2, varscan2
- DCLK1 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55214935; called by muse, mutect2, varscan2
- DCTN5 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1346952612, COSV55616716; called by muse, mutect2, varscan2
- DDX23 | c.2078C>T p.T693I | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56401174; called by muse, mutect2, varscan2
- DDX53 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 71/178 reads (40%) | catalogued as COSV60070204; called by muse, mutect2, varscan2
- DDX58 | c.1843T>C p.C615R | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101153373; called by muse, mutect2
- DENND5A | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV60238481; called by muse, mutect2, varscan2
- DERL1 | c.562T>G p.F188V | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV52366581; called by muse, mutect2, varscan2
- DGAT2 | c.1072T>C p.Y358H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930049; called by muse, mutect2
- DHODH | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs372609567; called by muse, mutect2, varscan2
- DHRS2 | c.141-1G>T p.X47_splice | Splice Site (SNP) | VAF 13/62 reads (21%) | catalogued as COSV51634698; called by muse, mutect2, varscan2
- DHX16 | c.1544+2T>C p.X515_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as COSV64565795; called by muse, mutect2, varscan2
- DHX38 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV51701384; called by muse, mutect2, varscan2
- DHX8 | c.3220C>T p.R1074W | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52254520; called by muse, mutect2, varscan2
- DIAPH2 | c.1285C>G p.L429V | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61295517; called by muse, mutect2, varscan2
- DIAPH2 | c.3233G>T p.R1078M | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV61295524; called by muse, mutect2, varscan2
- DIAPH3 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1195078497, COSV57382946; called by muse, mutect2, varscan2
- DIS3 | c.1387-1G>T p.X463_splice | Splice Site (SNP) | VAF 39/87 reads (45%) | catalogued as COSV66708268; called by muse, mutect2, varscan2
- DLG2 | c.278G>A p.R93K (on ENST00000650630 / NM_001351274.2; = p.R56K on NM_001142699.3) | Missense Mutation (SNP) | VAF 45/447 reads (10%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.015); catalogued as rs1227666314, COSV101075527; called by muse, mutect2, varscan2
- DLX5 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.099); catalogued as COSV56034623; called by muse, mutect2, varscan2
- DNAH10 | c.2520T>G p.N840K (on ENST00000409039; = p.N779K on NM_207437.3) | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.412); catalogued as COSV69004033; called by muse, mutect2, varscan2
- DNAH17 | c.7755C>T p.R2585= | Splice Region (SNP) | VAF 26/95 reads (27%) | catalogued as rs1296769925, COSV67751098, COSV67762255; called by muse, mutect2, varscan2
- DNAH2 | c.10112G>T p.G3371V | Missense Mutation (SNP) | VAF 102/281 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764768217, COSV66728600; called by muse, mutect2, varscan2
- DNAH5 | c.12814T>C p.F4272L | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV99447933; called by muse, mutect2
- DNAH8 | c.13291G>A p.V4431M | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762646929, COSV59485350; called by muse, mutect2, varscan2
- DNAJB13 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.701); catalogued as COSV60271335; called by muse, mutect2, varscan2
- DNAJC10 | c.2010A>C p.Q670H | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs751234532, COSV51148892; called by muse, mutect2, varscan2
- DNAJC25 | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57958117; called by muse, mutect2
- DNASE1L1 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50011424; called by muse, mutect2, varscan2
- DOCK4 | c.572A>C p.K191T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV101455898; called by muse, mutect2
- DOCK8 | c.3098C>T p.A1033V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV66624452; called by muse, mutect2, varscan2
- DOCK9 | c.6127G>A p.E2043K (on ENST00000376460 / NM_001366676.2; = p.E2044K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1329575302, COSV100239631, COSV59646244; called by muse, mutect2, varscan2
- DOK6 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs747193337, COSV66938786; called by muse, mutect2
- DPM1 | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100857770; called by muse, mutect2
- DPPA3 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.633); catalogued as COSV61503746; called by muse, mutect2, varscan2
- DRG1 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 114/480 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV58920309; called by muse, mutect2, varscan2
- DSG1 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.563); catalogued as rs368044134; called by muse, mutect2, varscan2
- DSG4 | c.1338A>G p.I446M | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100356507; called by muse, mutect2
- DST | c.15302T>G p.L5101R (on ENST00000361203 / NM_001374722.1; = p.L2689R on NM_015548.5) | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55045333; called by muse, mutect2, varscan2
- DTNB | c.1580A>G p.Q527R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV56485820; called by muse, mutect2, varscan2
- DUSP5 | c.898G>C p.V300L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV63647707; called by muse, mutect2, varscan2
- DYNC2H1 | c.10301C>T p.A3434V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV62108786; called by muse, mutect2, varscan2
- DYSF | c.4874C>A p.P1625H | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50640179, COSV99249777; called by muse, mutect2, varscan2
- EBF2 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68780923; called by muse, mutect2, varscan2
- ECHDC1 | c.94T>C p.Y32H (on ENST00000531967 / NM_001139510.1; = p.Y26H on NM_018479.3) | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV100541941; called by muse, mutect2
- EEF1G | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV57749706; called by muse, mutect2, varscan2
- EEF2 | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV58581177; called by muse, mutect2, varscan2
- EGLN1 | c.1235T>G p.V412G | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as COSV64150792; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 88/216 reads (41%) | catalogued as rs748937918; called by mutect2, varscan2
- ELP6 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV56133389; called by muse, mutect2, varscan2
- ENPP1 | c.1871T>C p.L624P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs775258307, COSV62937045; called by muse, mutect2, varscan2
- ENTPD1 | c.144G>A p.K48= | Splice Region (SNP) | VAF 22/110 reads (20%) | catalogued as COSV64604837; called by muse, mutect2, varscan2
- EP400 | c.8152C>T p.L2718F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57787926, COSV57788475; called by muse, mutect2, varscan2
- EPHA5 | c.1721T>C p.V574A | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV56678798; called by muse, mutect2, varscan2
- EPHA6 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 59/642 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101065992; called by muse, mutect2
- ERG | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as rs769957252, COSV55740391; called by muse, mutect2, varscan2
- ERGIC1 | c.158T>C p.V53A | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV58596363; called by muse, mutect2, varscan2
- EXO1 | c.2190del p.D731Tfs*4 | Frame Shift Del (DEL) | VAF 24/160 reads (15%) | catalogued as rs752940417; called by mutect2, varscan2
- EXOC6B | c.344A>T p.E115V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99726835; called by muse, mutect2
- EXPH5 | c.1729T>C p.F577L | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.329); catalogued as COSV56209356; called by muse, mutect2, varscan2
- FAM111B | c.1307del p.K436Rfs*6 | Frame Shift Del (DEL) | VAF 163/463 reads (35%) | catalogued as rs1435341780; called by mutect2, pindel, varscan2
- FAM120B | c.791T>C p.I264T | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53009001; called by muse, mutect2, varscan2
- FAM131B | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as COSV100577625, COSV58367480; called by muse, mutect2, varscan2
- FAM167A | c.278del p.P93Lfs*28 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as rs771396493; called by mutect2, varscan2
- FAM187B | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV61201383, COSV61201739; called by muse, mutect2, varscan2
- FAM189B | c.821G>A p.S274N | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV56947801; called by muse, mutect2, varscan2
- FAM217B | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as rs201204053; called by muse, mutect2, varscan2
- FAM83B | c.2836T>C p.S946P | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60927712; called by muse, mutect2, varscan2
- FANCM | c.6026C>A p.S2009Y | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57507579; called by muse, mutect2, varscan2
- FARSB | c.1412C>A p.P471Q | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99918737; called by muse, mutect2
- FAT3 | c.10732C>T p.Q3578* | Nonsense Mutation (SNP) | VAF 57/173 reads (33%) | catalogued as COSV53184245, COSV53185215; called by muse, mutect2, varscan2
- FBN1 | c.5476A>G p.N1826D | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV57332554; called by muse, mutect2, varscan2
- FBN1 | c.2309T>C p.V770A | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57332564; called by muse, mutect2, varscan2
- FBXO6 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV52419476; called by muse, mutect2, varscan2
- FCRL1 | c.803A>G p.E268G | Missense Mutation (SNP) | VAF 100/328 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV63827963; called by muse, mutect2, varscan2
- FCRL3 | c.1892A>G p.D631G | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV100943602; called by muse, mutect2
- FEM1A | c.919A>G p.T307A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54165086; called by muse, mutect2, varscan2
- FEM1A | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV54165097; called by muse, mutect2, varscan2
- FLG | c.9803C>T p.A3268V | Missense Mutation (SNP) | VAF 162/563 reads (29%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.965); catalogued as rs546424102, COSV64245916, COSV64251371; called by muse, mutect2, varscan2
- FLNB | c.5444A>G p.Y1815C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV55898784; called by muse, mutect2, varscan2
- FOXN3 | c.73T>C p.C25R | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs145541922; called by muse, mutect2, varscan2
- FPR2 | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 61/257 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1368957841, COSV60674716; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | catalogued as rs752538869; called by mutect2, pindel
- FRY | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as COSV66581758; called by muse, mutect2, varscan2
- FRYL | c.5763C>G p.S1921R | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV51964401; called by muse, mutect2, varscan2
- FUT6 | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV54609032; called by muse, mutect2, varscan2
- FXR1 | c.1766A>G p.D589G | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV99976730; called by muse, mutect2
- FXR2 | c.1075G>T p.A359S | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV51469762; called by muse, mutect2, varscan2
- FZD6 | c.1196T>C p.V399A | Missense Mutation (SNP) | VAF 213/554 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV62472871; called by muse, mutect2, varscan2
- GBP3 | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV52520272; called by muse, mutect2, varscan2
- GDF10 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs782375111; called by muse, mutect2, varscan2
- GEMIN5 | c.873G>A p.W291* | Nonsense Mutation (SNP) | VAF 103/291 reads (35%) | catalogued as COSV53565808; called by muse, mutect2, varscan2
- GJA9 | c.1352_1353del p.T451Sfs*15 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as rs1305818346; called by pindel, varscan2
- GLI2 | c.3848G>A p.R1283K (on ENST00000361492 / NM_001374353.1; = p.R1300K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); catalogued as COSV100082934, COSV58053149; called by muse, mutect2
- GLUL | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 185/687 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV59383613; called by muse, mutect2, varscan2
- GMPS | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 125/329 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55807722, COSV55807905, COSV99902842; called by muse, mutect2, varscan2
- GNA13 | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV104436281, COSV71474484; called by muse, mutect2, varscan2
- GNAI1 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs755993821, COSV63525598; called by muse, mutect2, varscan2
- GNAQ | c.932A>C p.K311T | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.139); catalogued as COSV54127364; called by muse, mutect2, varscan2
- GOLGA5 | c.304T>C p.S102P | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.593); catalogued as COSV50836527; called by muse, mutect2, varscan2
- GOLGA8A | c.1706C>T p.A569V (on ENST00000432566; = p.A541V on NM_181077.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753432137, COSV62171693; called by muse, mutect2, varscan2
- GPR173 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.272); catalogued as rs1556805893, COSV60238576; called by muse, mutect2
- GPRC5A | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 39/382 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs1334786172, COSV99185664; called by muse, mutect2, varscan2
- GPRC6A | c.1724G>T p.R575M | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as rs773407928, COSV59956429; called by muse, mutect2, varscan2
- GRIA3 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 180/470 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.519); catalogued as rs138008123, COSV52083104; called by muse, mutect2, varscan2
- GRIN2A | c.1138A>G p.N380D | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as rs1057519551, COSV58059186; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.2908T>C p.F970L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as COSV74206887; called by muse, mutect2, varscan2
- GRM1 | c.3013G>A p.A1005T | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.027); catalogued as rs1018640655, COSV51372450; called by muse, mutect2, varscan2
- GRM6 | c.1112G>A p.S371N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV51442080; called by muse, mutect2, varscan2
- GRM7 | c.2467A>G p.T823A | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); catalogued as rs1337841916, COSV63175722; called by muse, mutect2, varscan2
- GRN | c.1115G>A p.C372Y | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV50009642; called by muse, mutect2, varscan2
- GXYLT1 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV55140627; called by muse, mutect2, varscan2
- H1-6 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV58091626; called by muse, mutect2, varscan2
- HCLS1 | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100101306; called by muse, mutect2
- HEATR6 | c.2719C>T p.L907F | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51749553; called by muse, mutect2, varscan2
- HERC2 | c.9943G>A p.A3315T | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55353517; called by muse, mutect2, varscan2
- HERC3 | c.2026-2A>G p.X676_splice | Splice Site (SNP) | VAF 62/186 reads (33%) | catalogued as COSV52025872; called by muse, mutect2, varscan2
- HMCN1 | c.9616G>T p.G3206C | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54947547; called by muse, mutect2, varscan2
- HMCN1 | c.11045C>T p.A3682V | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV54947558; called by muse, mutect2, varscan2
- HMCN1 | c.14572A>G p.T4858A | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as COSV99637177; called by muse, mutect2
- HMOX2 | c.114G>T p.K38N | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54862039; called by muse, mutect2, varscan2
- HNRNPUL1 | c.2041_2043del p.N681del | In Frame Del (DEL) | VAF 18/94 reads (19%) | catalogued as rs766735739; called by pindel, varscan2
- HOXD10 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as COSV50906376; called by muse, mutect2, varscan2
- HOXD4 | c.438C>G p.N146K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60461125; called by muse, mutect2, varscan2
- HRNR | c.740A>G p.H247R | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs1464692466, COSV64263574; called by muse, mutect2, varscan2
- HTT | c.1844A>G p.E615G | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1291794655, COSV100751355; called by muse, mutect2
- HUWE1 | c.8794G>A p.A2932T | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.971); catalogued as COSV99474702; called by muse, mutect2
- IARS1 | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100986902; called by muse, mutect2
- IARS2 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.438); catalogued as COSV100228679; called by muse, mutect2
- IDH1 | c.251A>C p.E84A | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.459); catalogued as COSV61644940; called by muse, mutect2, varscan2
- IDNK | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs753634538, COSV99462097; called by muse, mutect2, varscan2
- IFNAR2 | c.1548A>G p.*516Wext*5 | Nonstop Mutation (SNP) | VAF 27/86 reads (31%) | catalogued as COSV51617090; called by muse, mutect2, varscan2
- IFRD2 | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.824); catalogued as COSV57115948; called by muse, mutect2, varscan2
- IGSF1 | c.3565G>T p.G1189C | Missense Mutation (SNP) | VAF 209/555 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV63840894; called by muse, mutect2, varscan2
- IGSF5 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66030735, COSV66030920; called by muse, mutect2
- IL6R | c.1337A>G p.N446S | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59817846; called by muse, mutect2, varscan2
- IL6ST | c.2170C>T p.H724Y | Missense Mutation (SNP) | VAF 164/396 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61143217; called by muse, mutect2, varscan2
- IPO9 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.194); catalogued as rs1461188192, COSV100843602; called by muse, mutect2
- IQCE | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs113031380, COSV100383158, COSV58077142; called by muse, mutect2, varscan2
- ITFG1 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57757609; called by muse, mutect2, varscan2
- ITGA8 | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65233619, COSV65237371; called by muse, mutect2, varscan2
- ITPR1 | c.4292A>T p.Y1431F (on ENST00000354582; = p.Y1416F on NM_002222.7) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57007215; called by muse, mutect2, varscan2
- ITPR2 | c.3929T>C p.L1310P | Missense Mutation (SNP) | VAF 214/1025 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67277261; called by muse, mutect2, varscan2
- ITPRID1 | c.1371T>A p.D457E | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.349); catalogued as COSV60084505; called by muse, mutect2, varscan2
- IZUMO2 | c.134A>G p.Q45R | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.035); catalogued as rs371774253, COSV53231581; called by mutect2, varscan2
- JDP2 | c.440A>T p.K147M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV50868654; called by muse, mutect2, varscan2
- JMJD1C | c.5386G>A p.E1796K | Missense Mutation (SNP) | VAF 65/282 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.118); catalogued as COSV59518263; called by muse, mutect2, varscan2
- KALRN | c.4717A>G p.K1573E | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1433794431, COSV53782450; called by muse, mutect2, varscan2
- KCNA3 | c.1340A>G p.Y447C | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901702; called by muse, mutect2, varscan2
- KCNH1 | c.2966G>A p.S989N (on ENST00000271751 / NM_172362.3; = p.S962N on NM_002238.4) | Missense Mutation (SNP) | VAF 70/365 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV55108100; called by muse, mutect2, varscan2
- KCNQ4 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.554); catalogued as COSV61272692; called by muse, mutect2
- KCTD13 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as COSV58161925; called by muse, mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 136/299 reads (45%) | catalogued as rs771545848; called by mutect2, varscan2
- KDM5B | c.3361A>G p.K1121E | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.044); catalogued as COSV52514067; called by muse, mutect2, varscan2
- KEAP1 | c.554T>C p.I185T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50648516, COSV50655833; called by muse, mutect2, varscan2
- KIAA2026 | c.2348A>G p.E783G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV67358224; called by muse, mutect2, varscan2
- KIF17 | c.1118T>C p.L373P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1467421996, COSV56123115; called by muse, mutect2, varscan2
- KIF17 | c.394A>T p.K132* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV56123124; called by muse, mutect2
- KIF20B | c.2602C>T p.R868* (on ENST00000371728 / NM_001284259.2; = p.R828* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 81/208 reads (39%) | catalogued as rs747822069, COSV53316731; called by muse, mutect2, varscan2
- KIF4A | c.3488A>T p.N1163I | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.107); catalogued as COSV65534610; called by muse, mutect2, varscan2
- KIR3DL1 | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV58496818; called by muse, mutect2, varscan2
- KIRREL2 | c.1742C>T p.T581I | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs762654118, COSV52880873; called by muse, mutect2, varscan2
- KLHL15 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 78/219 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.743); catalogued as COSV60142225; called by muse, mutect2, varscan2
- KLHL15 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 100/378 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as COSV60142232; called by muse, mutect2, varscan2
- KLHL2 | c.104A>T p.N35I | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56983676; called by muse, mutect2, varscan2
- KLHL25 | c.1556C>T p.T519M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.892); catalogued as rs774760536, COSV61996760; called by muse, mutect2, varscan2
- KLK4 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.056); catalogued as rs865893572, COSV60677367; called by muse, mutect2, varscan2
- KMT2D | c.16607T>C p.M5536T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56493297; called by muse, mutect2, varscan2
- KMT2D | c.6991del p.L2331* | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as CD1312976; called by pindel, varscan2
- KMT2D | c.6985G>A p.A2329T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.777); catalogued as rs938203622, COSV56493314; called by muse, varscan2
- KMT5B | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs868213710, COSV58565994; called by muse, mutect2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as rs764099275; called by mutect2, varscan2
- KNTC1 | c.5261C>T p.A1754V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV61085145; called by muse, mutect2, varscan2
- KRT27 | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV56973747; called by muse, mutect2, varscan2
- KSR1 | c.2098G>T p.G700* (on ENST00000644974 / NM_001367810.1; = p.G585* on NM_014238.2) | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV52040639; called by muse, mutect2, varscan2
- LAIR1 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.737); catalogued as rs768925392, COSV57310336; called by muse, mutect2, varscan2
- LAMC1 | c.4351T>C p.F1451L | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV51186176; called by muse, mutect2, varscan2
- LARS1 | c.404T>C p.I135T (on ENST00000394434 / NM_020117.11; = p.I108T on NM_016460.3) | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99198960; called by muse, mutect2
- LATS1 | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV53601385; called by muse, mutect2, varscan2
- LCE1E | c.134G>T p.S45I | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV100908581; called by muse, mutect2, varscan2
- LCE2D | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.037); catalogued as rs113433987; called by muse, mutect2, varscan2
- LCT | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV51558781; called by muse, mutect2, varscan2
- LEPR | c.1253G>A p.C418Y | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100756849; called by muse, mutect2
- LILRB1 | c.2084A>G p.Y695C (on ENST00000427581; = p.Y644C on NM_006669.6) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61122262; called by muse, mutect2, varscan2
- LIN7C | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 33/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53416716; called by muse, varscan2
- LIN7C | c.253A>C p.S85R | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV53416727; called by muse, varscan2
- LMTK2 | c.991A>G p.N331D | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52005475; called by muse, mutect2, varscan2
- LMTK3 | c.2950G>A p.A984T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV54318044; called by muse, mutect2, varscan2
- LONP1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as rs200781774, COSV100638791; called by muse, mutect2, varscan2
- LPGAT1 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs1466791928, COSV65352708; called by muse, mutect2, varscan2
- LRCH1 | c.866T>C p.I289T | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV100244143; called by muse, mutect2
- LRFN2 | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as rs766042098, COSV57835657, COSV57836826; called by muse, mutect2, varscan2
- LRIG3 | c.1326T>G p.N442K | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57871035; called by muse, mutect2, varscan2
- LRP1 | c.7163C>T p.A2388V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV54528723; called by muse, mutect2, varscan2
- LRP1B | c.13101del p.H4368Tfs*4 | Frame Shift Del (DEL) | VAF 61/229 reads (27%) | catalogued as rs751694974; called by mutect2, pindel, varscan2
- LRP5 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs773665226, COSV53725366; called by muse, mutect2
- LRP6 | c.2211G>C p.Q737H | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.851); catalogued as COSV53795932; called by muse, mutect2, varscan2
- LRRC20 | c.484G>A p.V162M (on ENST00000355790 / NM_207119.3; = p.V106M on NM_018205.4) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as rs755293571, COSV62939457; called by muse, mutect2, varscan2
- LRRC34 | c.890G>A p.R297H (on ENST00000446859 / NM_001172779.2; = p.R265H on NM_153353.5) | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as rs143470723, COSV57185725; called by muse, mutect2, varscan2
- LRRC52 | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV54234076; called by muse, varscan2
- LRRC6 | c.935A>G p.D312G | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51548403; called by muse, mutect2, varscan2
- LRRK2 | c.1140C>G p.Y380* | Nonsense Mutation (SNP) | VAF 26/110 reads (24%) | catalogued as COSV100111371; called by muse, mutect2
- LRRN2 | c.908A>G p.K303R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as COSV65784944; called by muse, mutect2, varscan2
- LY96 | c.79T>G p.S27A | Missense Mutation (SNP) | VAF 188/510 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV53027073; called by muse, varscan2
- LYPD6B | c.547C>A p.L183M (on ENST00000409029 / NM_001317004.1; = p.L207M on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/322 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs1320054950, COSV54521136; called by muse, mutect2, varscan2
- M6PR | c.176+2T>C p.X59_splice | Splice Site (SNP) | VAF 44/401 reads (11%) | catalogued as rs1440622216, COSV50004180; called by muse, mutect2, varscan2
- MACC1 | c.941T>G p.L314W | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.338); catalogued as COSV60547054; called by muse, mutect2, varscan2
- MACC1 | c.670T>C p.S224P | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100256362; called by muse, mutect2, varscan2
- MACF1 | c.3103T>C p.S1035P | Missense Mutation (SNP) | VAF 48/137 reads (35%) | catalogued as COSV58407564; called by muse, mutect2, varscan2
- MACF1 | c.21329A>G p.Y7110C (on ENST00000372915; = p.Y5155C on NM_012090.5) | Missense Mutation (SNP) | VAF 24/217 reads (11%) | catalogued as COSV57148686; called by muse, varscan2
- MAEL | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 45/248 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs202037854, COSV63304212; called by muse, mutect2, varscan2
- MAN2B2 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53457402; called by muse, mutect2, varscan2
- MAP3K1 | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs777628678, COSV68128001; called by muse, mutect2, varscan2
- MAP3K1 | c.2478G>T p.M826I | Missense Mutation (SNP) | VAF 107/279 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.885); catalogued as COSV68128009; called by muse, mutect2, varscan2
- MAP3K1 | c.4083T>G p.H1361Q | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68128022; called by muse, varscan2
- MAP3K3 | c.844T>C p.S282P | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV62282067; called by muse, mutect2, varscan2
- MAP3K4 | c.1009T>C p.Y337H | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100815739; called by muse, mutect2
- MAP3K5 | c.1037C>A p.A346D | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV62892702; called by muse, mutect2, varscan2
- MAPK13 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs183038663, COSV52985476; called by muse, mutect2, varscan2
- MAPRE1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.756); catalogued as COSV65033693; called by muse, mutect2, varscan2
- MARK1 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.379); catalogued as rs768967864, COSV100857096, COSV65072006; called by muse, mutect2, varscan2
- MAVS | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63927747; called by muse, mutect2, varscan2
- MBD5 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV68698403; called by muse, mutect2, varscan2
- MBTPS2 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 233/688 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.596); catalogued as COSV63412677; called by muse, mutect2, varscan2
- MDGA2 | c.1462G>A p.A488T (on ENST00000399232 / NM_001113498.2; = p.A190T on NM_182830.4) | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100636304, COSV62118685; called by muse, mutect2, varscan2
- MDM2 | c.961del p.L321Ffs*52 | Frame Shift Del (DEL) | VAF 98/315 reads (31%) | catalogued as rs746910913; called by mutect2, pindel, varscan2
- MDN1 | c.11377C>T p.R3793* | Nonsense Mutation (SNP) | VAF 36/80 reads (45%) | catalogued as rs1261354166, COSV65526042; called by muse, mutect2, varscan2
- ME3 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62771875, COSV62775548; called by muse, mutect2, varscan2
- MED12L | c.5326A>G p.K1776E | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV56400448; called by muse, mutect2, varscan2
- MED13 | c.4091G>T p.G1364V | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67267659; called by muse, mutect2, varscan2
- MED13L | c.4399G>A p.V1467M | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs774875010, COSV56132007; called by muse, mutect2, varscan2
- MED13L | c.1281G>A p.R427= | Splice Region (SNP) | VAF 16/157 reads (10%) | catalogued as COSV99930429; called by muse, mutect2, varscan2
- MED31 | c.30T>C p.D10= | Splice Region (SNP) | VAF 42/164 reads (26%) | catalogued as COSV56727388; called by muse, mutect2, varscan2
- MEIOC | c.1336A>G p.K446E | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63441714; called by muse, mutect2, varscan2
- MID1 | c.1675T>C p.Y559H | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as COSV100452764; called by muse, mutect2, varscan2
- MID2 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 34/657 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.679); catalogued as COSV53313624; called by muse, mutect2
- MKI67 | c.3766T>C p.S1256P | Missense Mutation (SNP) | VAF 142/352 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64077519; called by muse, mutect2, varscan2
- MMACHC | c.590A>T p.N197I | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53115242; called by muse, mutect2, varscan2
- MMS22L | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as rs1007868881, COSV99247874; called by muse, mutect2
- MON2 | c.4565T>C p.I1522T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs752765677, COSV54816550; called by muse, mutect2, varscan2
- MOSPD2 | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV100996961; called by muse, mutect2
- MPDZ | c.4834A>T p.I1612F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100057814; called by muse, mutect2, varscan2
- MRC1 | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 15/414 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1316257502; called by muse, mutect2
- MROH2B | c.2720G>T p.R907I | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68190316; called by muse, mutect2, varscan2
- MRPL37 | c.1243T>A p.L415I | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.763); catalogued as COSV60322990; called by muse, mutect2, varscan2
- MTHFD1 | c.478+2T>C p.X160_splice | Splice Site (SNP) | VAF 43/98 reads (44%) | catalogued as COSV53704326; called by muse, mutect2, varscan2
- MUL1 | c.1016G>A p.C339Y | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs910498807, COSV51643565; called by muse, mutect2, varscan2
- MYH4 | c.2003G>A p.S668N | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99702468; called by muse, mutect2
- MYH7 | c.5093C>T p.S1698F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV62524866; called by muse, mutect2, varscan2
- MYH8 | c.868del p.Y290Ifs*11 | Frame Shift Del (DEL) | VAF 24/139 reads (17%) | catalogued as rs1319380590; called by mutect2, pindel, varscan2
- MYO10 | c.4643C>T p.P1548L | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as rs377728133, COSV57031063; called by muse, mutect2, varscan2
- MYO18B | c.4828G>A p.D1610N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747579160, COSV59151199; called by muse, mutect2
- MYO3A | c.2972G>A p.R991Q | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764099857, COSV56352356, COSV99075848; called by muse, mutect2, varscan2
- MYOF | c.4721G>A p.C1574Y | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63711673; called by muse, mutect2, varscan2
- MYOF | c.1220dup p.V408Gfs*7 | Frame Shift Ins (INS) | VAF 29/91 reads (32%) | catalogued as rs752546951; called by mutect2, pindel, varscan2
- MYOZ1 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831954; called by muse, mutect2
- MYPN | c.3703C>T p.P1235S | Missense Mutation (SNP) | VAF 168/396 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV62740900; called by muse, mutect2, varscan2
- MYT1L | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.263); catalogued as rs1386585073, COSV67734448; called by muse, mutect2, varscan2
- NAB1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.094); catalogued as rs764007897, COSV61609548; called by muse, mutect2, varscan2
- NAV3 | c.5224G>A p.A1742T | Missense Mutation (SNP) | VAF 92/388 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs1036007513, COSV57116902; called by muse, mutect2, varscan2
- NCKAP5 | c.3367T>C p.S1123P | Missense Mutation (SNP) | VAF 16/291 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs1433712494, COSV100494710; called by muse, mutect2
- NCOA2 | c.3539G>A p.G1180D | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as COSV51224105; called by muse, mutect2, varscan2
- NCOR1 | c.5509T>C p.S1837P | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as COSV51999785; called by muse, mutect2, varscan2
- NDUFA4 | c.133T>C p.W45R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60012608; called by muse, mutect2, varscan2
- NDUFA8 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs370165868; called by muse, mutect2, varscan2
- NEK1 | c.2320A>G p.T774A | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV71458336; called by muse, mutect2, varscan2
- NEURL4 | c.3685-2A>C p.X1229_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV59753733; called by muse, mutect2, varscan2
- NEUROD6 | c.332A>T p.N111I | Missense Mutation (SNP) | VAF 94/423 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51773867; called by muse, mutect2, varscan2
- NF1 | c.1721+2T>C p.X574_splice | Splice Site (SNP) | VAF 6/58 reads (10%) | catalogued as CS030306, CS086409, COSV100647889, COSV62215053; called by muse, mutect2
- NFE2L2 | c.1010C>A p.A337E | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as COSV101229453; called by muse, mutect2
- NFKBIZ | c.581C>A p.P194Q | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV58202246; called by muse, mutect2, varscan2
- NFXL1 | c.905G>A p.S302N | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV61201130; called by muse, mutect2, varscan2
- NFYC | c.1375T>A p.*459Rext*91 (on ENST00000308733 / NM_001308114.1; = p.*336Rext*91 on NM_014223.5) | Nonstop Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV58130579; called by muse, mutect2, varscan2
- NHLRC3 | c.462dup p.G155Rfs*3 | Frame Shift Ins (INS) | VAF 39/109 reads (36%) | catalogued as rs745775817; called by mutect2, pindel, varscan2
- NID1 | c.2527+2T>A p.X843_splice | Splice Site (SNP) | VAF 19/137 reads (14%) | catalogued as COSV51630174; called by muse, mutect2, varscan2
- NLRC5 | c.4155G>A p.R1385= | Splice Region (SNP) | VAF 4/10 reads (40%) | catalogued as rs1163071253, COSV52664476; called by muse, mutect2, varscan2
- NLRC5 | c.5534A>G p.K1845R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV52664488; called by muse, mutect2, varscan2
- NLRP13 | c.1629del p.F543Lfs*8 | Frame Shift Del (DEL) | VAF 64/260 reads (25%) | catalogued as rs749541198; called by mutect2, pindel, varscan2
- NMBR | c.768del p.K256Nfs*45 | Frame Shift Del (DEL) | VAF 48/129 reads (37%) | catalogued as rs1470345555; called by mutect2, pindel, varscan2
- NOP14 | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as rs147582267; called by muse, mutect2, varscan2
- NOS1 | c.1979C>T p.T660I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57623401; called by muse, mutect2, varscan2
- NPAS2 | c.1088A>C p.E363A | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV59563075; called by muse, mutect2, varscan2
- NSD3 | c.1168T>C p.Y390H | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57622464; called by muse, mutect2, varscan2
- NT5C3B | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99505365; called by muse, mutect2
- NUP214 | c.2351A>G p.E784G | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1314715369, COSV63913631; called by muse, mutect2, varscan2
- NUP50 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs781273344, COSV61661686; called by muse, mutect2, varscan2
- NXPH2 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.815); catalogued as COSV99741400; called by muse, mutect2, varscan2
- OBSCN | c.2831C>T p.T944M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.455); catalogued as rs781470955, COSV52754207, COSV52769410; called by muse, mutect2, varscan2
- OPHN1 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100830853; called by muse, mutect2
- OR10W1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV67720955; called by muse, mutect2, varscan2
- OR2H2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 120/487 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs765028287, COSV63544943; called by muse, mutect2, varscan2
- OR2J3 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 241/647 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs1245431456, COSV65849824; called by muse, mutect2, varscan2
- OR2V2 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1261012404, COSV60316706; called by muse, mutect2, varscan2
- OR3A3 | c.341A>G p.H114R | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.517); catalogued as COSV52168866; called by muse, mutect2, varscan2
- OR4K14 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV59294535; called by mutect2, varscan2
- OR6C65 | c.305dup p.L102Ffs*18 | Frame Shift Ins (INS) | VAF 60/168 reads (36%) | catalogued as rs753853776; called by mutect2, varscan2
- OR7G2 | c.384dup p.A129Cfs*14 | Frame Shift Ins (INS) | VAF 86/254 reads (34%) | catalogued as rs750339447; called by mutect2, pindel, varscan2
- OR8G5 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 127/334 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58383650; called by muse, mutect2, varscan2
- ORC2 | c.215A>G p.E72G | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV99309792; called by muse, mutect2, varscan2
- OS9 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770299465, COSV57784915; called by muse, mutect2, varscan2
- OSMR | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 81/353 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs113665466, COSV99953217; called by muse, mutect2, varscan2
- OTOA | c.1324G>A p.V442I (on ENST00000286149; = p.V428I on NM_144672.4) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs1458895465, COSV53766008, COSV99625520; called by muse, mutect2, varscan2
- OTOP1 | c.1114T>C p.Y372H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56397655; called by muse, mutect2, varscan2
- OTOR | c.169T>A p.F57I | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55723182; called by muse, mutect2, varscan2
- OXNAD1 | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 98/345 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99551528; called by muse, mutect2
- PABPC3 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV55801998; called by muse, mutect2, varscan2
- PAGE5 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.864); catalogued as COSV99215886; called by muse, mutect2
- PAPOLG | c.713A>G p.N238S | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV53186237; called by muse, mutect2, varscan2
- PAQR6 | c.1013del p.G338Vfs*97 (on ENST00000292291 / NM_001272108.2; = p.V256Yfs*12 on NM_024897.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs747303869; called by mutect2, pindel
- PARP1 | c.236G>T p.W79L | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV64687395; called by muse, mutect2, varscan2
- PARP11 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as COSV57393777, COSV57398210; called by muse, mutect2, varscan2
- PASK | c.3580T>C p.Y1194H | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99300422; called by muse, mutect2
- PAXIP1 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV68188222; called by muse, mutect2, varscan2
- PCDH1 | c.3157C>A p.P1053T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.255); catalogued as COSV99747127; called by muse, mutect2
- PCDH1 | c.718C>A p.R240S | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54614549, COSV54620419; called by muse, mutect2, varscan2
- PCDHB7 | c.1577C>A p.A526E | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.273); catalogued as rs373682476, COSV50753762; called by muse, mutect2, varscan2
- PCDHB9 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs1391964681; called by muse, mutect2, varscan2
- PCDHGA12 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.015); catalogued as COSV52772990; called by muse, mutect2, varscan2
- PCDHGA12 | c.1691A>G p.Y564C | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs758159985, COSV52773017; called by muse, varscan2
- PCDHGA7 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.035); catalogued as rs559398944, COSV53944887; called by muse, mutect2, varscan2
- PCDHGC5 | c.1570T>C p.Y524H | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as COSV52773039; called by muse, mutect2, varscan2
- PCLO | c.9643G>A p.D3215N | Missense Mutation (SNP) | VAF 94/194 reads (48%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.976); catalogued as rs75551727, COSV61674223; called by muse, mutect2, varscan2
- PCLO | c.5247del p.G1750Efs*30 | Frame Shift Del (DEL) | VAF 243/736 reads (33%) | catalogued as COSV61646781; called by mutect2, pindel, varscan2
- PCSK6 | c.2188G>A p.V730M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs771085445, COSV100624580; called by muse, mutect2
- PCSK9 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56165514; called by muse, mutect2, varscan2
- PDHB | c.118A>G p.N40D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100240282; called by muse, mutect2
- PDK3 | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 61/154 reads (40%) | catalogued as rs868382375, COSV64794659; called by muse, varscan2
- PEG3 | c.3146A>G p.N1049S | Missense Mutation (SNP) | VAF 31/310 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99690746; called by muse, mutect2, varscan2
- PGBD4 | c.1751del p.N584Ifs*21 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | catalogued as rs770560794; called by mutect2, varscan2
- PHF7 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs746221390, COSV59982270; called by muse, mutect2, varscan2
- PHKA2 | c.838A>G p.K280E | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV101177579, COSV66055590; called by muse, mutect2
- PHKB | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV54536378; called by muse, mutect2, varscan2
- PHLDB3 | c.1772T>A p.L591* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV52672795; called by muse, mutect2, varscan2
- PHYHIPL | c.130A>G p.I44V | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV65850473; called by muse, mutect2, varscan2
- PI4KA | c.3179G>A p.R1060H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.459); catalogued as rs1405765241, COSV55425508; called by muse, mutect2, varscan2
- PIANP | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV57708587; called by muse, mutect2, varscan2
- PIKFYVE | c.4334A>G p.E1445G | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV52250187; called by muse, mutect2, varscan2
- PITPNA | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 84/361 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.202); catalogued as COSV57935839, COSV57936793; called by muse, mutect2, varscan2
- PKHD1 | c.3665G>A p.S1222N | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV61885216; called by muse, mutect2, varscan2
- PLAU | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV65642288; called by muse, mutect2
- PLCG1 | c.445A>G p.T149A | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV99719390; called by muse, mutect2
- PLCG1 | c.1913A>G p.H638R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54824954; called by muse, mutect2, varscan2
- PLSCR2 | c.682A>G p.I228V (on ENST00000497985 / NM_001199978.1; = p.I155V on NM_020359.2) | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs765457558, COSV60865165; called by muse, mutect2, varscan2
- PLXNA2 | c.5176A>G p.R1726G | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV65445724; called by muse, mutect2, varscan2
- PLXNA4 | c.3745C>T p.L1249F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV58164861; called by muse, mutect2, varscan2
- PLXNC1 | c.1726T>C p.F576L | Missense Mutation (SNP) | VAF 125/329 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV51577522; called by muse, mutect2, varscan2
- PLXND1 | c.4033G>A p.G1345S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223886297, COSV60720198; called by muse, mutect2, varscan2
- PM20D1 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as rs964719324, COSV65649157; called by muse, mutect2, varscan2
- PMEL | c.101G>C p.G34A | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV62428736, COSV62430331; called by muse, mutect2, varscan2
- PNMT | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99510838; called by muse, mutect2
- POC1B-GALNT4 | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.311); catalogued as COSV57969820; called by muse, mutect2, varscan2
- POLR1D | c.201T>A p.F67L | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV57256716; called by muse, mutect2, varscan2
- POLR2C | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.92); catalogued as COSV54674651; called by muse, mutect2, varscan2
- POLR2F | c.358del p.V120Wfs*159 | Frame Shift Del (DEL) | VAF 36/112 reads (32%) | catalogued as rs1293095997, COSV62807618; called by mutect2, pindel, varscan2
- POLR2M | c.375A>C p.Q125H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs375334112; called by muse, mutect2, varscan2
- POMGNT1 | c.1411A>G p.K471E | Missense Mutation (SNP) | VAF 16/99 reads (16%) | PolyPhen benign (0.409); catalogued as COSV64341220; called by muse, mutect2, varscan2
- PON1 | c.950T>C p.V317A | Missense Mutation (SNP) | VAF 124/295 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs1034127954, COSV55934181; called by muse, mutect2, varscan2
- POP1 | c.2671C>T p.H891Y | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.063); catalogued as COSV62894390; called by muse, mutect2, varscan2
- POT1 | c.1439A>G p.H480R | Missense Mutation (SNP) | VAF 95/378 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV62935391; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs377669149; called by muse, mutect2, varscan2
- PPFIBP1 | c.2341A>T p.I781F (on ENST00000318304 / NM_177444.3; = p.I775F on NM_003622.4) | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV57299775; called by muse, mutect2, varscan2
- PPP1R10 | c.964T>C p.F322L | Missense Mutation (SNP) | VAF 83/237 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV64740667; called by muse, mutect2, varscan2
- PPP1R13B | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV99163017; called by muse, mutect2
- PPP2R1A | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59046491; called by muse, mutect2, varscan2
- PREX2 | c.1693dup p.S565Ffs*3 | Frame Shift Ins (INS) | VAF 54/128 reads (42%) | catalogued as rs764112302; called by mutect2, varscan2
- PRF1 | c.1285G>T p.G429W | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100942593, COSV64615624, COSV64616023; called by muse, mutect2, varscan2
- PRKAA1 | c.1221G>A p.W407* | Nonsense Mutation (SNP) | VAF 18/135 reads (13%) | catalogued as COSV57186736; called by muse, mutect2, varscan2
- PRKCH | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.597); catalogued as COSV100273848; called by muse, mutect2
- PRKDC | c.9731A>G p.D3244G | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs745664111, COSV58066372; called by muse, mutect2, varscan2
- PRKDC | c.2198T>C p.L733P | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV58066384; called by muse, mutect2, varscan2
- PROS1 | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV67777614; called by muse, mutect2, varscan2
- PRPF4 | c.1249A>G p.N417D (on ENST00000374198 / NM_001322267.2; = p.N418D on NM_004697.5) | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.503); catalogued as rs1223232742, COSV65253538; called by muse, mutect2, varscan2
- PRR23B | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.57); catalogued as COSV61493226; called by muse, mutect2, varscan2
- PRSS12 | c.2377T>C p.F793L | Missense Mutation (SNP) | VAF 147/424 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV56611194; called by muse, mutect2, varscan2
- PRSS36 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51640324; called by muse, mutect2, varscan2
- PSIP1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 112/305 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV66255562; called by muse, varscan2
- PSMA1 | c.215T>A p.I72N | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV101123706; called by muse, mutect2
- PSMC3IP | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53819169; called by muse, mutect2, varscan2
- PSPC1 | c.950T>C p.L317S | Missense Mutation (SNP) | VAF 153/410 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.101); catalogued as COSV58891420; called by muse, varscan2
- PTAR1 | c.830C>A p.A277E | Missense Mutation (SNP) | VAF 118/423 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV61208612; called by muse, mutect2, varscan2
- PTGES3 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.997); catalogued as COSV56275065; called by muse, mutect2, varscan2
- PTPN13 | c.4877A>T p.Q1626L (on ENST00000411767 / NM_080683.3; = p.Q1607L on NM_006264.3) | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV100365225, COSV57419038; called by muse, mutect2, varscan2
- PTPRB | c.1865T>C p.V622A | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.687); catalogued as COSV99719344; called by muse, mutect2
- PTPRS | c.5438A>G p.Y1813C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53640066; called by muse, mutect2, varscan2
- QSER1 | c.4875G>T p.K1625N (on ENST00000399302; = p.K1754N on NM_001076786.3) | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV67901972; called by muse, mutect2, varscan2
- R3HCC1L | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as rs767091244, COSV54405924; called by muse, mutect2, varscan2
- RAB5C | c.566A>T p.N189I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV56793259; called by muse, mutect2, varscan2
- RABGAP1 | c.2482C>T p.Q828* | Nonsense Mutation (SNP) | VAF 37/197 reads (19%) | catalogued as COSV65381220; called by muse, mutect2, varscan2
- RAMP3 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as COSV99642477; called by muse, mutect2
- RAP1GAP2 | c.992T>C p.I331T | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV54590494; called by muse, mutect2, varscan2
- RBM39 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV53618435; called by muse, mutect2, varscan2
- RBSN | c.2308C>T p.R770W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs533990013, COSV53795975; called by muse, mutect2, varscan2
- RC3H1 | c.2363C>T p.P788L | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs140858270, COSV51223058; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS6 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV59602160; called by muse, mutect2, varscan2
- RHOU | c.617T>C p.L206S | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64209271; called by muse, mutect2, varscan2
- RIMS2 | c.460A>G p.S154G | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as COSV101267332; called by muse, mutect2
- RIMS2 | c.1875del p.G626Efs*3 (on ENST00000666250 / NM_001348490.2; = p.G434Efs*3 on NM_014677.5 and 7 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 44/167 reads (26%) | catalogued as rs1282720554; called by mutect2, pindel, varscan2
- RIPK2 | c.410A>T p.N137I | Missense Mutation (SNP) | VAF 144/360 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55135395; called by muse, mutect2, varscan2
- RNASE12 | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60088492; called by muse, mutect2, varscan2
- RNASE8 | c.258C>A p.N86K | Missense Mutation (SNP) | VAF 133/325 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV57551987; called by muse, mutect2, varscan2
- RNASEL | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV62378156; called by muse, mutect2, varscan2
- RNF17 | c.4033T>G p.S1345A | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs764410147, COSV99694670; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 60/100 reads (60%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPL19 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV56636613; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 38/109 reads (35%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRN3 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.043); catalogued as COSV99549184; called by muse, mutect2
- RSL1D1 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV63078651; called by muse, mutect2, varscan2
- RSPH3 | c.1343A>G p.Y448C (on ENST00000252655; = p.Y306C on NM_031924.8) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.855); catalogued as rs1413698882, COSV51925103; called by muse, mutect2, varscan2
- RTTN | c.2717T>C p.V906A | Missense Mutation (SNP) | VAF 208/770 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV55353650; called by muse, mutect2, varscan2
- RUNX1T1 | c.1753G>C p.A585P (on ENST00000265814 / NM_001198628.1; = p.A558P on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs57930555; called by muse, mutect2, varscan2
- RWDD4 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 142/353 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs752249282, COSV58393991; called by muse, varscan2
- RYK | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.331); catalogued as COSV56064858; called by muse, mutect2, varscan2
- RYR1 | c.10864A>G p.K3622E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV62113172; called by muse, mutect2, varscan2
- RYR2 | c.4724A>G p.H1575R | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63659318; called by muse, mutect2
- S1PR1 | c.197T>C p.V66A | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59514746; called by mutect2, varscan2
- SACS | c.11819T>C p.V3940A | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV66547774; called by muse, mutect2, varscan2
- SAG | c.1070T>C p.F357S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101300714; called by muse, mutect2
- SAGE1 | c.1202A>G p.N401S | Missense Mutation (SNP) | VAF 129/319 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV61018905; called by muse, mutect2, varscan2
- SALL2 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV58106292; called by muse, mutect2, varscan2
- SALL2 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.812); catalogued as COSV100444655; called by muse, mutect2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs753320334; called by mutect2, pindel
- SAMD9L | c.4192A>G p.K1398E | Missense Mutation (SNP) | VAF 141/1222 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV59086010; called by muse, mutect2, varscan2
- SCGN | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1302994078, COSV58547452; called by muse, mutect2, varscan2
- SCMH1 | c.1085A>G p.Y362C (on ENST00000326197 / NM_001031694.2; = p.Y315C on NM_012236.4) | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759445717, COSV58240757; called by muse, mutect2, varscan2
- SDAD1 | c.32G>T p.S11I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV62403956; called by muse, mutect2, varscan2
- SEC16A | c.4490T>C p.F1497S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51542459; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | catalogued as rs768388757; called by mutect2, pindel
- SEC24A | c.1076T>C p.M359T | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV59750264; called by muse, mutect2, varscan2
- SEC24C | c.2207T>A p.L736Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100227199; called by muse, mutect2
- SEC24D | c.2488G>A p.A830T | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV54885657; called by muse, mutect2, varscan2
- SEC24D | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99756946; called by muse, mutect2
- SEC61G | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV61856325; called by muse, mutect2, varscan2
- SECISBP2L | c.772T>C p.S258P | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV55938541; called by muse, mutect2, varscan2
- SEMA4A | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs151030269, COSV61772879; called by muse, mutect2, varscan2
- SENP7 | c.2357+2T>C p.X786_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as COSV58621278; called by muse, mutect2, varscan2
- SEPTIN10 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780288687, COSV100454214, COSV61780537; called by muse, mutect2, varscan2
- SEPTIN9 | c.223G>A p.A75T (on ENST00000427177 / NM_001113491.2; = p.A57T on NM_006640.4) | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.05); catalogued as COSV61211619; called by muse, mutect2, varscan2
- SERPINB12 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs543006776, COSV54035228; called by muse, mutect2, varscan2
- SETD1A | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs769871463, COSV52693361; called by muse, mutect2, varscan2
- SETDB2 | c.2152del p.I718Yfs*11 | Frame Shift Del (DEL) | VAF 45/180 reads (25%) | catalogued as rs775302281, COSV57902985; called by mutect2, varscan2
- SETX | c.7957A>G p.T2653A | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV56396435; called by muse, mutect2, varscan2
- SFI1 | c.2257T>C p.C753R (on ENST00000400288 / NM_001007467.3; = p.C722R on NM_014775.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as COSV63476026; called by muse, mutect2, varscan2
- SH3BP4 | c.431del p.G144Dfs*28 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as COSV60643230; called by mutect2, pindel, varscan2
- SH3D19 | c.1877A>G p.E626G | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV58794726; called by muse, mutect2, varscan2
- SHPK | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56650755; called by muse, mutect2, varscan2
- SI | c.2195C>T p.T732I | Missense Mutation (SNP) | VAF 167/627 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs772060606, COSV52282901, COSV52298917, COSV52304702; called by muse, mutect2, varscan2
- SIDT1 | c.1644G>T p.M548I | Missense Mutation (SNP) | VAF 107/313 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV53508312; called by muse, mutect2, varscan2
- SIGLEC8 | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV100367434; called by muse, mutect2
- SIPA1L3 | c.4517A>G p.Y1506C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.333); catalogued as COSV55925835; called by muse, mutect2, varscan2
- SIT1 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs770472286, COSV52400499; called by muse, mutect2, varscan2
- SKA3 | c.905G>A p.S302N | Missense Mutation (SNP) | VAF 91/218 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV53437556; called by muse, mutect2, varscan2
- SLC12A2 | c.2018T>C p.V673A | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.338); catalogued as COSV52477339; called by muse, mutect2, varscan2
- SLC24A5 | c.872-1G>A p.X291_splice | Splice Site (SNP) | VAF 89/222 reads (40%) | catalogued as COSV51054791; called by muse, mutect2, varscan2
- SLC25A23 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs143828533; called by muse, mutect2, varscan2
- SLC25A32 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1563717284, COSV99884738; called by muse, mutect2
- SLC25A52 | c.181A>G p.I61V (on ENST00000672005; = p.I51V on NM_001034172.4) | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV52504763; called by muse, mutect2, varscan2
- SLC2A12 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51603185; called by muse, mutect2, varscan2
- SLC30A9 | c.373T>C p.Y125H | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as rs1158223648, COSV100048181, COSV52560216; called by muse, mutect2, varscan2
- SLC34A1 | c.1472T>C p.V491A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV53693447; called by muse, mutect2, varscan2
- SLC35B4 | c.721T>C p.F241L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101043216; called by muse, mutect2, varscan2
- SLC38A5 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.898); catalogued as rs1556963291, COSV58335786; called by muse, varscan2
- SLC41A2 | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV51611910; called by muse, mutect2, varscan2
- SLC6A11 | c.395T>C p.I132T | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV54400037; called by muse, mutect2, varscan2
- SLC6A18 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57254956; called by muse, mutect2, varscan2
- SLC9A5 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV55365488; called by muse, varscan2
- SLCO5A1 | c.80G>T p.R27M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); catalogued as rs1285266346, COSV52669649; called by muse, mutect2, varscan2
- SLFN11 | c.2069G>T p.R690I | Missense Mutation (SNP) | VAF 100/267 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100390835, COSV57700908; called by muse, mutect2, varscan2
- SLFN5 | c.367A>G p.T123A | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55484135; called by muse, mutect2, varscan2
- SLFN5 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs763681518, COSV55483575, COSV55484148; called by muse, mutect2, varscan2
- SLITRK2 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV100158305; called by muse, mutect2
- SLITRK3 | c.1580C>T p.T527I | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.76); catalogued as rs112351427, COSV99580330; called by muse, mutect2, varscan2
- SLK | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs199902178, COSV59826929; called by muse, mutect2, varscan2
- SLTM | c.2456A>G p.Y819C | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100998916; called by muse, mutect2
- SLX4IP | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV57952254; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | catalogued as rs763364024; called by mutect2, varscan2*
- SMC3 | c.2005T>C p.Y669H | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs776056911, COSV100700079, COSV62421623; called by muse, mutect2
- SMC6 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.593); catalogued as rs748956536, COSV61171124; called by muse, mutect2, varscan2
- SMG7 | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 69/288 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as rs760532026, COSV61634753; called by muse, mutect2, varscan2
- SMPD1 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs755160837, CM041856, COSV54966551; called by muse, mutect2, varscan2
- SMURF1 | c.652C>T p.R218* | Nonsense Mutation (SNP) | VAF 31/140 reads (22%) | catalogued as COSV63160058; called by muse, mutect2, varscan2
- SNRPB | c.409C>A p.P137T | Missense Mutation (SNP) | VAF 47/381 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60016760; called by muse, mutect2, varscan2
- SORBS2 | c.3019T>C p.Y1007H (on ENST00000284776 / NM_021069.5; = p.Y573H on NM_003603.6) | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.525); catalogued as COSV99513139; called by muse, mutect2
- SORCS2 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as rs779008169, COSV61184969; called by muse, mutect2, varscan2
- SORL1 | c.1404+2T>C p.X468_splice | Splice Site (SNP) | VAF 24/113 reads (21%) | catalogued as COSV52763954; called by muse, mutect2, varscan2
- SORL1 | c.3963C>A p.F1321L | Missense Mutation (SNP) | VAF 18/458 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV99495759; called by muse, mutect2
- SOX6 | c.803T>C p.M268T | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100323478; called by muse, mutect2
- SP4 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 158/383 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56026945; called by muse, mutect2, varscan2
- SPATA21 | c.484A>G p.M162V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV59189054; called by muse, mutect2, varscan2
- SPEF2 | c.2662A>G p.K888E | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV61554348; called by muse, mutect2, varscan2
- SPEF2 | c.2738C>T p.T913I | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100609151, COSV61550978; called by muse, mutect2
- SPEN | c.5344G>T p.D1782Y | Missense Mutation (SNP) | VAF 12/365 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV101005710; called by muse, mutect2
- SPIC | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54692950; called by muse, mutect2, varscan2
- SPINK9 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.055); catalogued as COSV64958201; called by muse, mutect2, varscan2
- SPNS3 | c.400del p.R134Gfs*33 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | catalogued as COSV61070325; called by mutect2, pindel, varscan2
- SPOCD1 | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57100699; called by muse, mutect2, varscan2
- SREBF2 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 72/207 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63332957; called by muse, mutect2, varscan2
- SRRT | c.2250del p.F750Lfs*32 | Frame Shift Del (DEL) | VAF 25/147 reads (17%) | catalogued as COSV99574158; called by mutect2, pindel, varscan2
- SSR3 | c.29A>G p.Q10R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as rs978230261, COSV54021804; called by muse, mutect2
- ST14 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1206820372, COSV53837577; called by muse, mutect2
- STAG1 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 127/364 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52625607; called by muse, mutect2, varscan2
- STK40 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1204102843, COSV63737205; called by muse, mutect2
- STX11 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV62450715; called by muse, mutect2, varscan2
- STX4 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755136571, COSV58269523; called by muse, mutect2, varscan2
- SUPT5H | c.761T>C p.M254T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63242573; called by muse, varscan2
- SUZ12 | c.2013A>G p.I671M | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as COSV59503960; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 41/175 reads (23%) | catalogued as rs753462162; called by mutect2, varscan2
- SYCP2 | c.319T>C p.S107P | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV62773267; called by muse, mutect2, varscan2
- SYMPK | c.1880A>G p.Y627C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55616450; called by muse, mutect2, varscan2
- SYN3 | c.1069A>G p.K357E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60517929; called by muse, mutect2, varscan2
- SYNE1 | c.454G>A p.A152T (on ENST00000367255 / NM_182961.4; = p.A159T on NM_033071.3) | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750659947, COSV55124475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNM | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs782595494, COSV60375627; called by muse, mutect2, varscan2
- SYT11 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 82/469 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV64176374; called by muse, mutect2, varscan2
- SYTL2 | c.517T>C p.S173P | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100315067; called by muse, mutect2
- TAB3 | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV55841514; called by muse, mutect2, varscan2
- TAF1 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV52127798; called by muse, varscan2
- TAF1 | c.1550A>G p.K517R (on ENST00000373790 / NM_138923.4; = p.K538R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/277 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as rs1212022266, COSV52127818; called by muse, mutect2, varscan2
- TARBP1 | c.1962-1G>A p.X654_splice | Splice Site (SNP) | VAF 85/333 reads (26%) | catalogued as COSV50211705; called by muse, mutect2, varscan2
- TAS2R19 | c.396A>G p.I132M | Missense Mutation (SNP) | VAF 115/488 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV101115845; called by muse, mutect2, varscan2
- TBATA | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV54722162; called by muse, mutect2, varscan2
- TBCD | c.2575T>C p.Y859H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62809008; called by muse, mutect2, varscan2
- TBX15 | c.1523C>T p.A508V (on ENST00000369429 / NM_001330677.2; = p.A402V on NM_152380.3) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as COSV52871437; called by muse, mutect2, varscan2
- TBXAS1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV54937591; called by muse, mutect2, varscan2
- TCF7L2 | c.670G>A p.V224I (on ENST00000355995 / NM_001367943.1; = p.V201I on NM_030756.5) | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated (1); PolyPhen possibly damaging (0.564); catalogued as rs190966900, COSV53343832; called by muse, mutect2, varscan2
- TCP11L2 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as rs138884019, COSV54433174; called by muse, mutect2, varscan2
- TDRKH | c.1169A>G p.D390G | Missense Mutation (SNP) | VAF 15/221 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100162746; called by muse, mutect2
- TEAD2 | c.875G>C p.G292A | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs761174408, COSV60872763; called by muse, mutect2, varscan2
- TEDDM1 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 85/283 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV62380800; called by muse, mutect2, varscan2
- TENM4 | c.7805A>G p.H2602R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV53677377; called by muse, mutect2, varscan2
- TENM4 | c.6391A>G p.N2131D | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53677402; called by muse, mutect2, varscan2
- TET2 | c.824A>G p.N275S | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.095); catalogued as rs1042729299, COSV54412531; called by muse, mutect2, varscan2
- TFAP2C | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV52373609, COSV99571516; called by muse, mutect2, varscan2
- TFCP2 | c.1280A>G p.Y427C | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1208837022, COSV99227889; called by muse, mutect2
- THBS3 | c.2044G>A p.V682I | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs1018367114, COSV100857732; called by muse, mutect2
- THOC2 | c.3679A>T p.T1227S | Missense Mutation (SNP) | VAF 39/369 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV55557133; called by muse, mutect2, varscan2
- THSD1 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.685); catalogued as rs538615273, COSV51632332; called by muse, mutect2, varscan2
- TJP1 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62047244; called by muse, mutect2, varscan2
- TLCD3A | c.369T>A p.H123Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56747840; called by muse, mutect2, varscan2
- TM4SF18 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV56060203; called by muse, mutect2, varscan2
- TMC4 | c.343T>C p.Y115H (on ENST00000617472 / NM_001145303.3; = p.Y109H on NM_144686.4) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV55478063; called by muse, mutect2, varscan2
- TMEFF2 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV55842210; called by muse, mutect2, varscan2
- TMEM101 | c.710T>C p.M237T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV52814361; called by muse, mutect2, varscan2
- TMEM131 | c.1728G>A p.E576= | Splice Region (SNP) | VAF 28/120 reads (23%) | catalogued as COSV51788003; called by muse, mutect2, varscan2
- TMEM131L | c.3676G>A p.A1226T | Missense Mutation (SNP) | VAF 169/549 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53651451; called by muse, mutect2, varscan2
- TMEM132E | c.2405A>G p.Y802C (on ENST00000321639; = p.Y892C on NM_001304438.2) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100396487; called by muse, mutect2
- TMEM52B | c.119T>C p.V40A (on ENST00000381923 / NM_001079815.1; = p.V20A on NM_153022.4) | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV53727633; called by muse, mutect2
- TMEM62 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 179/429 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs549676915, COSV53042607; called by muse, mutect2, varscan2
- TOP2B | c.1967G>A p.R656H (on ENST00000264331 / NM_001330700.2; = p.R651H on NM_001068.3) | Missense Mutation (SNP) | VAF 93/468 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs757502615, COSV51968590; called by muse, mutect2, varscan2
- TOX | c.439A>G p.T147A | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV63851403; called by muse, varscan2
- TRAPPC9 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1251870728, COSV66909568; called by muse, mutect2
- TRIM26 | c.845del p.K282Rfs*16 | Frame Shift Del (DEL) | VAF 22/148 reads (15%) | catalogued as rs1271434984; called by mutect2, varscan2
- TRIM45 | c.1355C>G p.P452R | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV56715134; called by muse, mutect2, varscan2
- TRIM56 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV100047858; called by muse, mutect2
- TRIML1 | c.1123C>A p.L375M | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV60197257; called by muse, mutect2, varscan2
- TRMT10B | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs540903572, COSV53052015; called by muse, mutect2, varscan2
- TRPA1 | c.1274del p.G425Afs*5 | Frame Shift Del (DEL) | VAF 23/190 reads (12%) | catalogued as rs759260579; called by mutect2, varscan2
- TRPV1 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs61753456, COSV51514901; called by muse, mutect2, varscan2
- TRRAP | c.8225A>G p.Q2742R (on ENST00000359863 / NM_001244580.1; = p.Q2724R on NM_003496.3) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV62855954; called by muse, mutect2, varscan2
526 further variants in this file (224 protein-altering or splice-affecting, 270 silent, 32 other) are not listed here.
